Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A4MX, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A4MX-01A (Primary Tumor).

[page 1 of 6]
FINAL DIAGNOSIS:

- A. Right frontal mass: Diffuse astrocytoma (WHO grade 2). Features suggest anaplastic change. See note.
- B. Tumor cyst wall: Scattered astrocytoma cells within white matter.
- C. Right frontal mass: Diffuse astrocytoma (WHO grade 2). See note.
- D. Tumor cyst wall: Scattered astrocytoma cells within white matter.
- E. Middle - right frontal mass: Scattered astrocytoma cells within white matter.
- F. Deep cyst wall: Cortex and white matter with cyst wall lined by moderately cellular, viable tumor (15% of total tissue). Adjacent white matter with only scattered glioma cells.
- G. Anterior cyst wall: Cyst wall lined by moderately cellular, viable tumor (10% of total tissue). The adjacent white matter shows no definite tumor (intraoperative smear G reviewed, and shows no tumor).
- H. Deep to cyst wall: Fragments of white matter with mild hypercellularity and few atypical cells. No cellular tumor.

Technical Performing Location: _____
questions regarding this case:

For

Page 1 of 7

ICD-0-3
astrocytoma, diffuse 9400/3
Site: brain, frontal lobe c71.1

fw
10/4/12

NIH/PA Discrepancy		

[page 2 of 6]
I. Deep to cyst wall: White matter with cyst wall lined by moderately cellular, viable tumor.

Comment: This astrocytoma diffusely infiltrates white and gray matter. In some areas, especially the cyst wall, the cells are associated with prominent microcystic change. Tumor cells have moderately pleomorphic astrocytic nuclei, some naked and others with gemistocytic cytoplasm; other areas have a more round, monotonous pattern suggestive of an oligodendroglioma component. Immunostain for p53 is diffusely positive, however, arguing against an oligodendroglioma. Perineuronal satellitosis is seen. No evidence of an underlying grade 1 tumor is seen (i.e. no EGBs, Rosenthal fibers or noninfiltrative areas). No mitoses are present. Though the cellularity and pleomorphism are in some areas pronounced, no mitoses, vascular endothelial proliferation or necrosis are present. Immunostain for MIB-1 (slide C3) shows a nuclear labeling rate of up to 6% (rates of greater than 3% are considered likely to represent anaplastic change by Burger et al., Surgical Pathology of the Nervous System and its Coverings, 4th ed.). Thus the tumor is WHO grade 2, but is likely to represent early anaplastic change. Molecular testing for MGMT, 1p19q are in progress.

BRAIN: Resection

MACROSCOPIC

Specimen Type

☒ Resection

Specimen Size

Greatest dimension: 4.3 x 4 x up to 2.7 cm

Tumor Site

☒ Cerebrum: right frontal

Tumor Size

☒ Cannot be determined

MICROSCOPIC

Histologic Type

☒ Astrocytoma, diffuse

Histologic Grade

☒ WHO Grade 2

[page 3 of 6]
Margins

X Cannot be assessed

***Additional Studies**

* X Molecular testing (specify): See above

Frozen Section Diagnosis:

- A. **Right frontal mass** (16 minutes)
- Infiltrating glioma, features of an oligodendroglioma.
- B. **Tumor cyst wall** (17 minutes)
- Glioma.
- D. **Foci of tumor present** (10 minutes)
- F. **(white matter, SMF1): Glioma present.**
(cortex, SMF2): No tumor seen. (10 minutes)
- G. **Anterior cyst wall**
- Benign.
- I. **Deep cyst wall**
- Tumor present.

Gross Description:

- A. Received fresh labeled with the patient's name, _____, " and "right frontal mass," is an aggregate of tan-white tissue, fragments ranging from 0.3 cm to 0.6 cm in greatest dimension, which are entirely submitted in _____
- B. Received fresh labeled with the patient's name, _____, " and "tumor cyst wall," is a 1.0 x 0.3 x 0.2 cm fragment of tan-white tissue, which is trisected and entirely submitted in _____
- C. Received fresh, labeled with patient's name, _____ and "right frontal mass," is a 22 gram, 4.3 x 4 x up to 2.7 cm piece of irregular gray-tan brain tissue. The specimen is step sectioned to reveal gray-tan-white cut surface. A portion of the tissue is taken for brain bank.

[page 4 of 6]
Representative sections (about 30% of the total specimen) are submitted in cassette 1

- D. Received fresh, labeled with patient's name, _____ and "tumor cyst wall," is a 1.1 x 0.7 x 0.2 cm irregular piece of gray-white soft tissue which is trisected and entirely submitted in cassette
- E. Received fresh, labeled with patient's name, _____, "_____," and "middle - right frontal mass," is a 1.1 x 0.4 x 0.1 cm piece of irregular gray-white soft tissue which is entirely submitted in cassette
- F. Received fresh, labeled with patient's name, _____, "_____," and "deep cyst wall," is a 2.3 gram, 3 x 2.2 x up to 0.8 cm piece of irregular gray-white soft tissue which is cross sectioned to reveal gray-tan cortex with gray-white white matter. The specimen is entirely submitted in cassettes _____
- G. Received fresh, labeled with patient's name, _____ and "anterior cyst wall," is a 0.6 gram, 2 x 1.1 x up to 0.4 cm piece of irregular white-tan soft tissue which is step sectioned and entirely submitted in cassettes
- H. Received fresh, labeled with patient's name, _____ and "deep to cyst wall," is a 0.2 gram, 1 x 0.6 x 0.2 cm aggregate of multiple fragments of gray-white soft tissue which is entirely submitted in cassette
- I. Received fresh, labeled with patient's name, _____ and "deep to cyst wall," is a 0.1 gram, 1 x 0.5 x 0.1 cm piece of irregular gray-white soft tissue which is sectioned and entirely submitted in cassette

Microscopic Description:

20 H&E; p53 immunostain, MIB1, semiquant.

I have reviewed all diagnostic slides and have edited the gross and/or microscopic portion of this report as part of my pathologic assessment and final diagnosis.

[page 5 of 6]
Amended Molecular Analysis Report

Test Performed

MGMT Methylation Assay

Specimen Type

Paraffin Block

Result

Gene Methylation DETECTED.

Methylation of the MGMT (O(6)-methylguanine-DNA methyltransferase) gene was detected using methylation specific PCR technologies.

Methylation Score: 5.67

unmethylated <2.00

methylated >=2.00

Background

MGMT (O(6)-methylguanine-DNA methyltransferase) is a DNA repair enzyme that is involved in the repair of damage caused by a variety of DNA crosslinking compounds, including alkylating agents. Increased methylation of the MGMT gene promoter region causes diminished or silenced expression of the gene, making cells more sensitive to DNA damage. This relationship has been shown for glioblastomas and alkylating agents such as Temodar(R)(temozolomide).

Approximately 40% to 45% of glioblastoma multiforme (GBM) tumors exhibit MGMT gene methylation. Retrospective studies have shown that detection of MGMT promoter methylation in tumor samples is associated with an increased likelihood of a favorable response to temozolomide.

Methodology

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimen. Molecular analysis of the MGMT gene is performed by methylation-specific PCR and detected on ABI7900. The MGMT and beta-Actin copy numbers will be used to calculate the ratio of MGMT/beta-Actin x1000. Molecular-based testing is highly accurate, but as in any laboratory test, rare diagnostic errors may occur.

Results of this test are for Investigational Purposes Only. The performance characteristic of this assay have been determined by . The result should not be used as a diagnostic procedure without confirmation of the diagnosis by another medically established diagnostic product or procedure.

Comments

Block ID:

Reference

[page 6 of 6]
1. Vlassenbroeck I. et al. Validation of Real-Time Methylation-Specific PCR to Determine O(6)-Methylguanine-DNA Methyltransferase Gene Promoter Methylation in Glioma. J. Molecular Diagnostics 10; 4:332-337. 2008.
2. Hegi M. et al. MGMT Gene Silencing and Benefit from Temozolomide in Glioblastoma. New England J Medicine 352; 10:997-1003. 2005.
3. Brandes A. et al. MGMT Promoter Methylation Status Can Predict the Incidence and Outcome of Pseudoprogression After Concomitant Radiochemotherapy in Newly Diagnosed Glioblastoma Patients. J. Clinical Oncology 26; 13:2192-2197. 2008.
4. Hau P. et al. MGMT Methylation Status: The Advent of Stratified Therapy in Glioblastoma. Disease Markers 23:97-104. 2007.

Director Review:

DISCLAIMER:

Testing performed at

Revision Reason:

*** AMENDED REPORT *** (Previously reported _____)

This amended report is issued to correct a typographical error in the original report. The sentence in the Result section has been changed from "Methylation of the MGMT (O(6)-methylguanine-DNA methyltransferase) gene was not detected using methylation specific PCR technologies." to "Methylation of the MGMT (O(6)-methylguanine-DNA methyltransferase) gene was detected using methylation specific PCR technologies." There are no other changes to the original report.

Page 1 of 2

This document contains private and confidential health information protected by state and federal law. If you received this document in error,

Chromosome studies performed by FISH on paraffin blocks of tumor (_____
report _____, showed the following:

Chromosome 1p intact.

Chromosome 19q intact.

Immunostain for IDH1 _____ is positive.

Source: NCI Genomic Data Commons file e806b202-25e8-4c76-afb8-dc87beff2e6d (TCGA-FG-A4MX.E88FF565-EFD8-4E5D-87BC-A7210DE9F29C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).